Somatic mutation profile of tumor specimen MMRF_2005_1_BM_CD138pos (aliquot MMRF_2005_1_BM_CD138pos_T1_KBS5U_L07281) from MMRF case MMRF_2005, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.5 years (19,534 days).
Specimen MMRF_2005_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f51197-78d8-4227-9c05-366dbd6ee6b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2005_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2005_1_PB_Whole_C3_KBS5U_L07282; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a50980a-edc9-4e19-a03d-c4283c7eac37

The open-access MAF lists 113 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 33, Intron 13, Silent 10, Nonsense Mutation 5, 3'Flank 3, Frame Shift Del 2, RNA 2, 5'Flank 2, In Frame Del 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DIS3 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706780, COSV66707774; called by muse, mutect2, varscan2
- CARMIL2 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs557350135, COSV58023055, COSV58023962; called by muse, mutect2, varscan2
- CCDC113 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 65/242 reads (27%) | catalogued as rs763584066, COSV99541136; called by muse, mutect2, varscan2
- CD109 | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.582); catalogued as rs370006037; called by muse, mutect2, varscan2
- DLX6 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs1223331635, COSV99142495; called by muse, mutect2
- EFTUD2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53656001; called by muse, mutect2
- FAT4 | c.13414G>C p.G4472R | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100627126; called by muse, mutect2
- HOXB3 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.022); catalogued as rs960914562; called by muse, mutect2
- IGHV2-70 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs373474286; called by muse, varscan2
- IGHV2-70D | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs1424503844; called by muse, varscan2
- ISL2 | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV51959161, COSV51959208; called by muse, mutect2
- PGR | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54806249; called by muse, mutect2
- PLXNA1 | c.3577G>A p.G1193S | Missense Mutation (SNP) | VAF 99/163 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146550621; called by muse, mutect2, varscan2
- PPP5C | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV50139119, COSV99183486; called by muse, mutect2, varscan2
- PRKAA2 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs758394696; called by muse, mutect2, varscan2
- TRIM65 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs566802344; called by muse, mutect2, varscan2
- WDFY3 | c.6916G>C p.E2306Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV55694667; called by muse, mutect2, varscan2
- ABCC8 | c.838_875del p.G280Pfs*90 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- AHR | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- AMBRA1 | c.262_264dup p.V88dup | In Frame Ins (INS) | VAF 23/40 reads (58%) | called by mutect2, pindel, varscan2
- CD19 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLIP1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBNL | c.1186A>G p.N396D (on ENST00000448521 / NM_001014436.3; = p.N397D on NM_014063.7) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FOLH1B | n.1189A>T | Splice Region (SNP) | VAF 22/381 reads (6%) | called by muse, mutect2
- FRG1 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 63/100 reads (63%) | called by muse, mutect2, varscan2
- GPRASP1 | c.1558T>A p.S520T | Missense Mutation (SNP) | VAF 74/76 reads (97%) | SIFT tolerated (0.18); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HDLBP | c.3354del p.R1119Efs*58 | Frame Shift Del (DEL) | VAF 44/250 reads (18%) | called by mutect2, pindel, varscan2
- IMPG2 | c.3405_3410del p.R1136_E1137del | In Frame Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- LARS1 | c.2847T>G p.H949Q (on ENST00000394434 / NM_020117.11; = p.H922Q on NM_016460.3) | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.1331-1G>T p.X444_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- NKTR | c.3101A>G p.Q1034R | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, varscan2
- OR2L13 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 23/289 reads (8%) | called by muse, mutect2
- OSBPL7 | c.2190T>G p.H730Q | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- PLXNA3 | c.4849A>C p.M1617L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- PPA2 | c.868T>C p.C290R (on ENST00000341695 / NM_176869.3; = p.C261R on NM_006903.4) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PRG3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RETREG2 | c.1064G>C p.R355P | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RNF165 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- ROBO2 | c.3092T>A p.M1031K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SI | c.2365T>A p.L789I | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- SLC20A1 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC24A3 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2
- SORL1 | c.1889A>T p.Y630F | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF230 | c.1249A>C p.K417Q | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ARHGEF38 | c.2082T>C p.S694= | Silent (SNP) | VAF 163/307 reads (53%) | called by muse, mutect2, varscan2
- FER1L5 | c.5121G>A p.L1707= (on ENST00000623019; = p.L1680= on NM_001293083.2) | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs957039252; called by muse, mutect2, varscan2
- FGA | c.1680C>T p.S560= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- KYNU | c.573G>A p.K191= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- NKTR | c.3180A>G p.K1060= | Silent (SNP) | VAF 65/124 reads (52%) | called by muse, varscan2
- PDZRN3 | c.2016C>T p.D672= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs777027867; called by muse, mutect2, varscan2
- PHF3 | c.4575T>A p.V1525= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- PRKCD | c.1335T>C p.F445= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- TFPT | c.732C>T p.Y244= | Silent (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- ZHX3 | c.279G>T p.V93= | Silent (SNP) | VAF 121/260 reads (47%) | called by muse, mutect2, varscan2
- ALS2CL | c.*658A>G | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF11 | chr1:156935065 G>A | 3'Flank (SNP) | VAF 25/59 reads (42%) | catalogued as rs190040963; called by muse, mutect2, varscan2
- CAP1P1 | n.783T>A | RNA (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- CCDC74A | c.295+284G>A | Intron (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2
- CDH8 | c.*105G>C | 3'UTR (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- CEMIP | c.*2029G>C | 3'UTR (SNP) | VAF 63/137 reads (46%) | called by muse, mutect2, varscan2
- CEMIP | c.*2030G>T | 3'UTR (SNP) | VAF 62/136 reads (46%) | called by muse, mutect2, varscan2
- CNTN3 | c.*548T>C | 3'UTR (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- CSPG4P13 | n.1626G>A | RNA (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- CTSH | c.932+18C>T | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- DLGAP2 | c.*6819G>A | 3'UTR (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- EPHA3 | c.*928A>G | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*2147A>T | 3'UTR (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- FAM131B | c.*1724_*1727del | 3'UTR (DEL) | VAF 20/220 reads (9%) | catalogued as rs1267261881; called by mutect2, pindel
- FAM162A | c.372+92G>T | Intron (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- FBXO40 | c.*1897G>A | 3'UTR (SNP) | VAF 14/83 reads (17%) | catalogued as rs550200176; called by muse, mutect2, varscan2
- FLRT2 | chr14:85529103 G>A | 5'Flank (SNP) | VAF 104/208 reads (50%) | called by muse, mutect2, varscan2
- GABRG1 | c.*1002T>C | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- GLI3 | c.*1689T>C | 3'UTR (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-5542T>G | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as rs993619988; called by muse, mutect2
- HHLA1 | c.140-1112A>G | Intron (SNP) | VAF 107/221 reads (48%) | called by muse, mutect2, varscan2
- HINT1 | c.*189A>G | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- HMBS | c.825+27C>T | Intron (SNP) | VAF 83/249 reads (33%) | catalogued as rs757340140; called by muse, mutect2, varscan2
- HSD17B13 | c.*87dup | 3'UTR (INS) | VAF 32/173 reads (18%) | called by mutect2, pindel, varscan2
- JMJD7 | c.*267G>T | 3'UTR (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- LHX9 | c.*822del | 3'UTR (DEL) | VAF 42/86 reads (49%) | catalogued as rs966561339; called by mutect2, varscan2
- LMO3 | c.206+6419A>G | Intron (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- LRCH4 | c.*774C>T | 3'UTR (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- LTB | c.162+82C>T | Intron (SNP) | VAF 36/76 reads (47%) | catalogued as rs569397869; called by muse, mutect2, varscan2
- LTN1 | c.*2167T>C | 3'UTR (SNP) | VAF 37/171 reads (22%) | called by muse, varscan2
- NADSYN1 | c.799-1243G>A | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as rs1051072065; called by muse, mutect2, varscan2
- NSUN4 | c.*174T>C | 3'UTR (SNP) | VAF 74/172 reads (43%) | called by muse, mutect2
- PAWR | c.*1355G>C | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- PNLIPRP3 | c.*517A>C | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- POGK | c.*2576A>G | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- RAE1 | c.*240G>C | 3'UTR (SNP) | VAF 14/144 reads (10%) | catalogued as COSV64797757; called by muse, mutect2
- RFK | chr9:76394442 G>A | 5'Flank (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- RUFY1 | c.*139C>T | 3'UTR (SNP) | VAF 19/39 reads (49%) | catalogued as rs542947513; called by mutect2, varscan2
- SLC17A2 | chr6:25913301 T>A | 3'Flank (SNP) | VAF 176/353 reads (50%) | called by muse, mutect2, varscan2
- SLC19A3 | c.*561A>C | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- SLC2A4 | c.*821G>A | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- SNF8 | c.*503A>G | 3'UTR (SNP) | VAF 35/77 reads (45%) | catalogued as rs1216775259; called by muse, mutect2, varscan2
- SPINT1 | c.-66+105C>T | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- SPTSSB | c.*1085A>T | 3'UTR (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- ST14 | c.441-223A>C | Intron (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- STEAP3 | c.*491A>T | 3'UTR (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- STIP1 | c.1559+76G>A | Intron (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- STPG2 | c.*2929G>T | 3'UTR (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- TENM2 | chr5:168263291 C>T | 3'Flank (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- THNSL1 | c.*25dup | 3'UTR (INS) | VAF 40/100 reads (40%) | catalogued as rs763779047; called by mutect2, varscan2
- THSD4 | c.*5943C>T | 3'UTR (SNP) | VAF 22/115 reads (19%) | catalogued as rs1259615081; called by muse, mutect2, varscan2
- TMC3 | c.*766C>T | 3'UTR (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- TNS3 | c.4194-714del | Intron (DEL) | VAF 53/108 reads (49%) | catalogued as rs1180310938; called by mutect2, varscan2
- TTC26 | c.*298A>G | 3'UTR (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- TTC30A | c.*1405C>T | 3'UTR (SNP) | VAF 59/134 reads (44%) | called by muse, mutect2, varscan2
- USP13 | c.*4355T>A | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ZKSCAN4 | c.*131G>A | 3'UTR (SNP) | VAF 20/222 reads (9%) | catalogued as rs1270644668; called by muse, mutect2
- ZNF652 | c.*2412A>T | 3'UTR (SNP) | VAF 20/27 reads (74%) | called by muse, mutect2, varscan2
